Gene-level copy-number profile of tumor specimen TCGA-13-1489-02A from TCGA case TCGA-13-1489, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 70.5 years (25,768 days).
Specimen TCGA-13-1489-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.cd423cd2-5b84-4397-b64c-967f74a1186f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1489-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 404 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second ASCAT2 file.
https://portal.gdc.cancer.gov/files/6ab093de-e93b-4ddc-8fff-340da23e557f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 593; copy number 1: 3,267; copy number 2: 23,708; copy number 3: 14,021; copy number 4: 14,919; copy number 5: 1,948; copy number 6: 1,500; copy number 7: 213; copy number 8: 19; copy number 9: 25; copy number 10: 2; copy number 12: 4.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:49,374,201–49,691,523, 2 genes (within-gene range 0–3): AGBL4-IT1, AL390023.1.
- chr4:10,199,823–10,295,579, 8 genes: AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:77,216,416–77,216,878, 1 gene: AC008638.3.
- chr12:114,077,133–114,241,770, 5 genes: AC010183.1, AC010183.2, HAUS8P1, GLULP5, LINC02459.
- chr20:59,577,509–59,847,711, 1 gene (within-gene range 0–5): PHACTR3.
- chr20:59,852,667–59,852,728, 1 gene: RNU7-141P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,711 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–154,678,345, 498 genes, copy number 5 (broad region; genes not listed).
- chr1:237,862,175–248,919,946, 270 genes, copy number 5 (broad region; genes not listed).
- chr3:140,865,075–198,222,513, 1,002 genes, copy number 6–7 (broad region; genes not listed).
- chr4:68,537,184–68,712,498, 6 genes, copy number 7: UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15, AC147055.1.
- chr5:62,776,877–62,777,263, 1 gene, copy number 6: ISCA1P1.
- chr5:93,583,222–94,176,029, 11 genes, copy number 5: NR2F1, AC106818.1, FAM172A, MIR2277, AC106818.2, NPM1P27, POU5F2, AC108102.1, AC099501.1, AC114980.1, AC117528.1.
- chr5:141,330,571–141,512,981, 4 genes, copy number 6 (within-gene range 2–6): PCDHGA1, PCDHGA2, PCDHGA3, PCDHGB1.
- chr5:141,355,021–141,512,979, 16 genes, copy number 6 (within-gene range 2–6): PCDHGA4, PCDHGB2, PCDHGA5, PCDHGB3, PCDHGA6, PCDHGA7, PCDHGB4, PCDHGA8, PCDHGB5, PCDHGA9, PCDHGB6, PCDHGA10, PCDHGB7, PCDHGA11, PCDHGB8P, AC005618.2.
- chr5:141,439,853–141,442,449, 1 gene, copy number 6: PCDHGB9P.
- chr5:181,065,086–181,342,213, 27 genes, copy number 7: AC008620.1, FOXO1B, AC008620.2, OR2V1, OR2V2, LINC01962, AC008443.4, TRIM7, TRIM7-AS1, AC008443.3, AC008443.7, TRIM41, MIR4638, AC008443.1, RACK1, SNORD96A, SNORD95, CTC-338M12.4, TRIM52, TRIM52-AS1, AC008443.6, AC008443.2, AC008443.5, RNU6-705P, AC138035.1, AC138035.3, AC138035.2.
- chr6:17,092,714–18,122,677, 18 genes, copy number 5: AL138740.1, STMND1, AL136305.1, RBM24, AL034372.1, CAP2, RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1, NHLRC1.
- chr6:26,477,872–29,313,017, 153 genes, copy number 5 (broad region; genes not listed).
- chr7:6,754,109–26,647,305, 265 genes, copy number 6–9 (broad region; genes not listed).
- chr7:75,769,533–76,541,459, 32 genes, copy number 5: CCL26, CCL24, AC005102.1, RHBDD2, POR, MIR4651, RPL7L1P3, SNORA14A, TMEM120A, STYXL1, AC006330.1, MDH2, AC005077.4, RNU6-863P, GTF2IP7, AC005077.2, AC005077.1, AC005077.3, SRRM3, HSPB1, YWHAG, PPIAP81, SSC4D, ZP3, DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16.
- chr7:76,818,377–86,217,733, 95 genes, copy number 5–10 (within-gene range 1–10) (broad region; genes not listed).
- chr7:94,782,886–95,615,132, 19 genes, copy number 6: GRPEL2P3, RN7SKP129, ARF1P1, PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4.
- chr8:6,499,632–8,199,973, 113 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:104,330,324–109,121,565, 51 genes, copy number 6: DPYS, DCSTAMP, AP003471.1, AP002847.1, MIR548A3, LRP12, NDUFA5P2, ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR.
- chr9:90,462,899–94,109,856, 83 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr10:87,859,158–87,863,533, 1 gene, copy number 5: KLLN.
- chr10:87,878,692–87,880,427, 1 gene, copy number 5: AC063965.2.
- chr10:108,296,099–108,296,532, 1 gene, copy number 6: PTGES3P5.
- chr10:114,690,143–115,948,999, 10 genes, copy number 6 (within-gene range 3–6): PPIAP19, AL137025.1, TAF9BP2, FAM160B1, RPL15P13, TRUB1, RNU6-1121P, LINC02626, ATRNL1, AC016042.1.
- chr10:120,851,305–121,928,492, 13 genes, copy number 6–7 (within-gene range 4–13): WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA.
- chr11:38,618,264–39,261,213, 5 genes, copy number 5 (within-gene range 3–5): LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P.
- chr11:72,754,729–75,140,148, 82 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr11:75,131,138–75,131,880, 1 gene, copy number 6: OR2AT1P.
- chr11:89,177,875–95,071,224, 161 genes, copy number 5–6 (broad region; genes not listed).
- chr11:128,522,390–128,522,449, 1 gene, copy number 6: MIR6090.
- chr13:57,391,171–67,267,706, 75 genes, copy number 5–9 (broad region; genes not listed).
- chr14:72,969,451–77,653,055, 168 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr14:105,836,765–106,473,000, 118 genes, copy number 5 (broad region; genes not listed).
- chr15:70,503,907–77,485,607, 218 genes, copy number 5 (broad region; genes not listed).
- chr15:98,437,162–101,933,350, 96 genes, copy number 5 (broad region; genes not listed).
- chr17:41,029,697–41,266,641, 30 genes, copy number 5: KRTAP1-4, KRTAP1-3, KRTAP1-1, KRTAP2-1, KRTAP2-2, KRTAP2-3, KRTAP2-4, KRTAP2-5P, KRTAP4-7, AC100808.1, KRTAP4-8, KRTAP4-16, KRTAP4-9, KRTAP4-11, KRTAP4-12, KRTAP4-6, KRTAP4-5, KRTAP4-4, KRTAP4-3, KRTAP4-2, KRTAP4-1, KRTAP4-17P, KRTAP9-1, KRTAP9-12P, KRTAP9-2, KRTAP9-3, KRTAP9-8, KRTAP9-4, KRTAP9-9, KRTAP9-6.
- chr18:63,476,958–63,505,085, 2 genes, copy number 5 (within-gene range 1–5): SERPINB5, AC036176.3.
- chr20:58,150,902–59,516,039, 43 genes, copy number 5 (within-gene range 3–5): C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, AL160410.1, PIEZO1P1, AL389889.2, AL389889.1.
- chr20:59,624,904–59,628,295, 1 gene, copy number 5: PHACTR3-AS1.
- chr21:18,953,264–19,900,043, 11 genes, copy number 6: AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683.
- chr21:23,065,491–23,131,206, 4 genes, copy number 12 (within-gene range 4–12): AP001116.1, MIR6130, ZNF299P, MSANTD2P1.

Autosomal genes at a single copy (total copy number 1): 3,177. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
